Somatic mutation profile of tumor specimen TCGA-FY-A3NM-01A (aliquot TCGA-FY-A3NM-01A-11D-A21A-08) from TCGA case TCGA-FY-A3NM, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 48.6 years (17,734 days).
Specimen TCGA-FY-A3NM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc430357-ece2-4524-b2a7-d952c798c249.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FY-A3NM-10A (Blood Derived Normal), aliquot TCGA-FY-A3NM-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60030d66-ef57-4718-a9e7-2a959700a184

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1orf210 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV70682516; called by muse, mutect2, varscan2
- DNMT3A | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.57); catalogued as COSV53065678; called by muse, mutect2, varscan2
- INTS14 | c.1205A>G p.N402S (on ENST00000313182 / NM_001366360.2; = p.N323S on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs768681172, COSV57527995; called by muse, mutect2, varscan2
- NPFFR2 | c.1316A>G p.N439S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as COSV58152006; called by muse, mutect2, varscan2
- SLC26A8 | c.1966G>C p.A656P | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as COSV62886786; called by muse, mutect2, varscan2
- TPBG | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.38); catalogued as rs1454422058, COSV100869773; called by mutect2, varscan2
- CNTLN | c.678G>A p.K226= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs756546991, COSV52087625; called by muse, mutect2, varscan2
- DPP8 | c.2673T>G p.R891= (on ENST00000341861 / NM_001320875.2; = p.R775= on NM_017743.6) | Silent (SNP) | VAF 65/138 reads (47%) | catalogued as COSV55681096; called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622814 G>T | 3'Flank (SNP) | VAF 9/230 reads (4%) | catalogued as COSV57543821; called by muse, mutect2
